Surgical pathology report (de-identified scan), TCGA case TCGA-XF-A9SX, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-A9SX-01A (Primary Tumor).

[page 1 of 6]
Collected

Ordered by

Location

DIAGNOSIS:

RADICAL CYSTECTOMY WITH BILATERAL PELVIC LYMPH NODE DISSECTION, URINARY DIVERSION,
RIGHT COLON POUCH TO UMBILICUS WITH GASTROSTOMY TUBE:

RIGHT DISTAL URETER (A):

FROZEN SECTION DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- NO DYSPLASIA OR CARCINOMA IDENTIFIED

LEFT DISTAL URETER (B):

FROZEN SECTION DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- NO DYSPLASIA OR MALIGNANCY IDENTIFIED

INNER AORTAL CAVAL LYMPH NODES (C):

FROZEN SECTION DIAGNOSIS:

- NO TUMOR IDENTIFIED IN TWO LYMPH NODES (0/2)

FINAL DIAGNOSIS:

- MICROSCOPIC FOCUS OF METASTATIC CARCINOMA INVOLVING ONE OF TWO
LYMPH NODES (1/2)

- TUMOR NOT SEEN ON RE-REVIEW OF FROZEN SECTION SLIDES

BLADDER, RIGHT AND LEFT PELVIC LYMPH NODES (D):

BLADDER:

GROSS DIAGNOSIS:

- TUMOR IDENTIFIED EXTENDING INTO PERIVESICAL SOFT TISSUE

FINAL DIAGNOSIS:

- UROTHELIAL CARCINOMA, POORLY DIFFERENTIATED, GRADE 4/4, MEASURING 4 CM
IN GREATEST DIMENSION, WITH EXTENSION THROUGH MUSCULARIS PROPRIA INTO
PERIVESICAL FAT

- TUMOR EXTENDS TO PERITONEUM

- LYMPHOVASCULAR INVASION IDENTIFIED

- FOCAL CARCINOMA IN SITU

- RADIAL, URETHRAL, RIGHT AND LEFT URETER AND VAGINAL SURGICAL MARGINS,
NEGATIVE FOR CARCINOMA

- URETHRA, NEGATIVE FOR TUMOR

- TUMOR DOES NOT EXTEND INTO VAGINA

- CHRONIC CYSTITIS

RIGHT PELVIC LYMPH NODES:

- NO LYMPH NODES IDENTIFIED (0/0)

- NO TUMOR IDENTIFIED

LEFT PELVIC LYMPH NODES:

- METASTATIC CARCINOMA IDENTIFIED IN THREE OF THREE LYMPH NODES (3/3)

RIGHT PARACAVAL LYMPH NODES (E):

- NO METASTATIC CARCINOMA IDENTIFIED IN TWO LYMPH NODES (0/2)

RIGHT COMMON ILIAC LYMPH NODES (F):

- METASTATIC CARCINOMA IDENTIFIED IN TWO OF TEN LYMPH NODES (2/10)

LEFT PARA AORTIC LYMPH NODES (G):

- NO METASTATIC CARCINOMA IDENTIFIED EIGHT LYMPH NODES (0/8)

LEFT COMMON ILIAC LYMPH NODES (H):

ICD-O-3

Carcinoma, urothelial NOS
8120/3

Site Bladder NOS C67.9

12/3/26/14

[page 2 of 6]
Collected:

Ordered by:

- NO METASTATIC CARCINOMA IDENTIFIED IN 11 LYMPH NODES (0/11)

RIGHT NODE OF CLOQUET (I):

- FIBROADIPOSE TISSUE ONLY
- NO LYMPH NODES IDENTIFIED (0/0)
- NO CARCINOMA IDENTIFIED

RIGHT EXTERNAL ILIAC LYMPH NODES (J):

- FIBROADIPOSE TISSUE ONLY
- NO LYMPH NODES IDENTIFIED (0/0)
- NO CARCINOMA IDENTIFIED

RIGHT OBTURATOR / HYPOGASTRIC LYMPH NODES (K):

- METASTATIC CARCINOMA IDENTIFIED IN TWO OF 13 LYMPH NODES
- TUMOR COMPLETELY REPLACES ONE OF THE LYMPH NODES AND MEASURES 2.1 CM IN GREATEST DIMENSION GROSSLY
- BENIGN GLANDS OF MULLERIAN TYPE WITHIN PERINODAL SOFT TISSUE HAVING ADJACENT SUTURE GRANULOMA (SEE COMMENT)

LEFT NODE OF CLOQUET (L):

- NO METASTATIC CARCINOMA IDENTIFIED IN FOUR LYMPH NODES (0/4)

LEFT EXTERNAL ILIAC LYMPH NODES (M):

- NO METASTATIC CARCINOMA IDENTIFIED IN SIX LYMPH NODES (0/6)

LEFT OBTURATOR / HYPOGASTRIC LYMPH NODES (N):

- NO METASTATIC CARCINOMA IDENTIFIED TEN LYMPH NODES (0/10)

PRESACRAL LYMPH NODE (O):

- NO METASTATIC CARCINOMA IDENTIFIED ONE LYMPH NODE (0/1)

RIGHT PRESACRAL LYMPH NODES (P):

- NO METASTATIC CARCINOMA IDENTIFIED IN ONE LYMPH NODE (0/1)

LEFT PRESACRAL LYMPH NODES (Q):

- ADIPOSE TISSUE ONLY
- NO LYMPH NODES IDENTIFIED (0/0)
- NO CARCINOMA IDENTIFIED

LEFT PROXIMAL URETER, MARGIN (R):

- NO DYSPLASIA OR CARCINOMA IDENTIFIED

RIGHT PROXIMAL URETER, MARGIN (S):

- NO DYSPLASIA OR CARCINOMA IDENTIFIED

LYMPH NODE SUMMARY: METASTATIC CARCINOMA IDENTIFIED IN SIX OF 71 LYMPH
NODES EXAMINED

PATHOLOGIC TNM STAGE: pT3bN2MX

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

Collected
Ordered by

COMMENT:

The endosalpinigotic gland noted within the perinodal soft tissue of specimen K probably resulted from prior gynecologic surgery as the adjacent suture granuloma would suggest. These glands are benign and probably of no clinical significance.

SPECIMEN SOURCE:

- A: "R. distal ureter-F/S"
- B: "L. distal ureter-F/S"
- C: "Inner aortal caval L. nodes-F/S"
- D: "Bladder"
- E: "R. para caval lymph nodes"
- F: "R. common iliac L. nodes"
- G: "Left para aortic lymph nodes"
- H: "L. common iliac lymph nodes"
- I: "R. node of cloquet"
- J: "R. external iliac lymph nodes"
- K: "R. obturator/hypogastric L. nodes"
- L: "L. node of cloquet"
- M: "L. external iliac lymph nodes"
- N: "L. obturator hypogastric L. nodes"
- O: "Pre sacral lymph nodes"
- P: "R. presciatic L. nodes"
- Q: "Left presciatic L. nodes"
- R: "L. proximal ureter (margin)"
- S: "R. proximal ureter (margin)"

CLINICAL INFORMATION:

Pertinent History & Clinical Findings: Hx of hysterectomy

Pre-Op Dx: Bladder cancer

Post-Op Dx: Same

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labelled "R. distal ureter-F/S". It consists of a 0.4 x 0.3 x 0.2 cm portion of ureter which is entirely submitted for frozen section in cassette AFS.

B: The specimen is received fresh from the O.R. and labelled "L. distal ureter-F/S". It consists of a 0.7 x 0.3 x 0.3 cm segment of ureter. The specimen is entirely submitted for frozen section in cassette BFS.

C: The specimen is received fresh from the O.R. and labelled "Inner aortal caval L. nodes-F/S". It consists of a fragment of yellow fatty tissue measuring 2.5 x 1.5 x 0.5 cm. Two lymph nodes are grossly identified. These are bisected and entirely submitted for frozen section in cassette CFS. The remaining tissue is submitted in cassette CRT.

D: The specimen is received fresh from the O.R. and labelled "Bladder". It consists of a cystectomy specimen measuring 16 x 12 x 4 cm overall. The bladder measures 9 x 8 x 4 cm. The urethra measures 3 x 1.5 cm. A portion of anterior vaginal wall measuring 4 x 1.5 x 0.5 cm is also present. The right distal ureter is 7 cm in length and 0.5 cm in circumference and the left distal ureter is 6 cm in length and 0.5 cm in circumference. The peritoneum is focally involved by tumor. Within the bladder dome is a 4 x 3 x 3 cm firm, white, infiltrating and ulcerating tumor mass which grossly invades into the perivesical fat and extends to and involves the peritoneum. The remaining bladder mucosa is grossly unremarkable.

[page 4 of 6]
Collected
Ordered by:

Location:

Both ureters have grossly unremarkable mucosa. The urethra appears uninvolved by tumor. The vaginal mucosa is tan-white without tumor involvement. In the right perivesical soft tissue no lymph nodes are identified. In the left perivesical soft tissue, two firm areas are noted. One is 3 cm and the other 1.7 cm in greatest dimension. Representative sections are submitted in 21 cassettes.

E: The specimen is received in formalin and labelled "R. para caval lymph nodes". It consists of a 2.3 x 2.1 x 0.3 cm fragment of tan-pink and yellow soft tissue. A 1.5 cm lymph node is grossly evident. The entire specimen is submitted in one cassette.

F: The specimen is received in formalin and labelled "R. common iliac L. nodes". It consists of multiple fragments of yellow fatty tissue measuring 5 x 4 x 0.6 cm in aggregate. Multiple lymph nodes up to 1.6 cm are identified. The entire specimen is submitted in six cassettes.

G: The specimen is received in formalin and labelled "Left para aortic lymph nodes". It consists of a 2.1 x 1.9 x 0.5 cm fragment of yellow fatty tissue two grossly identifiable lymph nodes up to 1.7 cm are identified. The entire specimen is submitted in one cassette.

H: The specimen is received in formalin and labelled "L. common iliac lymph nodes". It consists of two fragments of pink and yellow fatty tissue measuring 3 x 2 x 0.5 cm in aggregate. Multiple lymph nodes up to 1.5 cm are identified. The entire specimen is submitted in two cassettes.

I: The specimen is received in formalin and labelled "R. node of cloquet". It consists of two fragments of yellow fatty tissue measuring 1.5 x 1.5 x 0.3 cm in aggregate. Lymph nodes are inconspicuous. The entire specimen is submitted in one cassette.

J: The specimen is received in formalin and labelled "R. external iliac lymph nodes". It consists of two fragments of yellow fatty tissue measuring 2.5 x 2 x 0.5 cm. Lymph nodes are inconspicuous. The entire specimen is submitted in two cassettes.

K: The specimen is received in formalin and labelled "R. obturator/hypogastric L. nodes". It consists of multiple fragments of yellow and pink fatty tissue measuring 4.5 x 3.5 x 2 cm in aggregate. A 2.1 cm grossly positive lymph node is identified. Multiple other lymph nodes are also present. Representative sections are submitted in four cassettes.

L: The specimen is received in formalin and labelled "L. node of cloquet". It consists of multiple fragments of yellow fatty tissue measuring 3 x 1.7 x 0.5 cm. Three possible lymph nodes are identified measuring up to 1.7 cm are identified. The entire specimen is submitted in two cassettes.

M: The specimen is received in formalin and labelled "L. external iliac lymph nodes". It consists of multiple fragments of yellow fatty tissue measuring 3 x 2 x 0.5 cm in aggregate. Multiple lymph nodes up to 1.7 cm are identified. The entire specimen is submitted in three cassettes.

N: The specimen is received in formalin and labelled "L. obturator hypogastric L. nodes". It consists of multiple fragments of yellow fatty tissue measuring 6 x 4 x 1 cm in aggregate. Multiple lymph nodes up to 1.6 cm are identified. A 1.6 cm lymph node has a focal white firm area measuring 0.7 cm. Representative sections are submitted in six cassettes.

O: The specimen is received in formalin and labelled "Pre sacral lymph nodes". It consists of multiple fragments of red and yellow soft tissue measuring 4 x 2 x 1

[page 5 of 6]
Collected:
Ordered by:

cm in aggregate. Lymph nodes are inconspicuous. The entire specimen is submitted in one three cassettes.

P: The specimen is received in formalin and labelled "R. presciatic L. nodes". It consists of multiple fragments of yellow fatty tissue measuring 2 x 1 x 0.5 cm in aggregate. A 0.6 cm lymph node is identified. The entire specimen is submitted in one cassette.

Q: The specimen is received in formalin and labelled "Left presciatic L. nodes". It consists of multiple fragments of yellow fatty tissue measuring 1.5 x 1.5 x 0.5 cm in aggregate. Lymph nodes are inconspicuous. The entire specimen is submitted in one cassette.

R: The specimen is received in formalin and labelled "L. proximal ureter (margin)". It consists of a 1.3 x 1.2 x 0.5 cm specimen containing a segment of ureter measuring 1.2 cm in length and 0.4 cm in diameter. Representative sections are submitted in one cassette.

S: The specimen is received in formalin and labelled "R. proximal ureter (margin)". It consists of a 1 x 0.7 x 0.4 cm specimen containing a 0.5 cm long segment of ureter having diameter of 0.4 cm. Representative sections are submitted in one cassette.

SECTIONS:

AFS:	frozen section, right distal ureter
BFS:	frozen section, left distal ureter
CFS:	frozen section, inner aortal caval lymph nodes
CRT:	remaining tissue
D1:	right ureter margin
D2:	left ureter margin
D3:	distal urethral margin
D4:	distal vaginal margin
D5:	right vaginal margin
D6:	left vaginal margin
D7:	right ureterovesical junction
D8:	left ureterovesical junction
D9:	trigone
D10:	bladder neck and urethra
D11:	mid urethra
D12:	posterior bladder wall
D13,14:	posterior bladder wall and tumor
D15:	posterior bladder wall, tumor, and peritoneum
D16:	tumor
D17:	tumor with perivesical fat
D18,19:	representative section of right perivesical soft tissue
D20:	1.7 cm firm area, left perivesical soft tissue
D21:	3 cm firm area and left perivesical soft tissue
E:	right paracaval lymph nodes - all embedded
F1:	right common iliac lymph nodes; single bisected lymph node
F2:	single bisected lymph node
F3-6:	remaining specimen
G:	left para-aortic lymph nodes - all embedded
H1:	left common iliac lymph nodes; single bisected lymph node
H2:	remaining tissue with lymph node
I:	right node of cloquet - all embedded
J1,2:	right external iliac lymph nodes - all embedded
K1:	right obturator/hypogastric lymph nodes; positive lymph node
K2-4:	remaining lymph nodes
L1,2:	lymph node of cloquet - all embedded
M1-3:	left external iliac lymph nodes - all embedded

[page 6 of 6]
Collected:

Ordered by:

N1: left obturator hypogastric lymph nodes; bisected lymph node with firm white area
N2-6: remaining possible lymph nodes
O1-3: presacral lymph nodes - all embedded
P: right. presciatic lymph nodes - all embedded
Q: left presciatic lymph nodes - all embedded
R: left. proximal ureter (margin) - representative section
S: right proximal ureter (margin) - representative section

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Right distal ureter:
- no tumor identified

BFS: Left distal ureter:
- no tumor identified

CFS: Inner aortal caval lymph node:
- no tumor identified in two lymph nodes (0/2)

INTRAOPERATIVE GROSS CONSULTATION

D: Bladder:
- tumor identified extending into perivesical soft tissue

MICROSCOPIC EXAMINATION:

A-S: See final microscopic-diagnosis.

Source: NCI Genomic Data Commons file 6978602b-6e96-4b77-8dab-dce7a872c798 (TCGA-XF-A9SX.FFF56041-E252-4438-BD4A-C7FD5295A061.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).